Somatic mutation profile of tumor specimen TCGA-AG-3599-01A (aliquot TCGA-AG-3599-01A-02D-1989-10) from TCGA case TCGA-AG-3599, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 70.5 years (25,749 days).
Specimen TCGA-AG-3599-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d71b5ac6-b300-4a9a-9253-d9e031bf88ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3599-10A (Blood Derived Normal), aliquot TCGA-AG-3599-10A-01W-1990-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d3980c2-259e-48ab-b280-1939049b0cbc

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2, Splice Region 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM11 | c.1566G>A p.Q522= | Splice Region (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99567258; called by muse, mutect2, varscan2
- CES4A | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs537976908, COSV100110023; called by muse, mutect2, varscan2
- COL24A1 | c.3398G>A p.R1133K | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100993092; called by muse, mutect2, varscan2
- DHX9 | c.1249A>G p.K417E | Missense Mutation (SNP) | VAF 148/406 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100841319; called by muse, mutect2, varscan2
- DLG2 | c.2426A>C p.K809T | Missense Mutation (SNP) | VAF 140/626 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV99713927; called by muse, mutect2, varscan2
- ECHDC1 | c.875G>A p.G292E (on ENST00000531967 / NM_001139510.1; = p.G286E on NM_001002030.2) | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100541634; called by muse, mutect2, varscan2
- HYDIN | c.3307T>C p.S1103P | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as rs766766284, COSV101141690; called by muse, mutect2, varscan2
- KIAA0232 | c.2070A>G p.I690M | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.352); catalogued as rs1363822473, COSV100300563; called by muse, mutect2, varscan2
- MIDEAS | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV54098459; called by muse, mutect2, varscan2
- PLCG2 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs781434235, COSV63869621; called by muse, mutect2, varscan2
- PLSCR3 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247892; called by muse, mutect2
- PTX4 | c.986G>T p.G329V (on ENST00000447419 / NM_001328608.2; = p.G324V on NM_001013658.1) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99560313; called by muse, mutect2
- RAD52 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs368534549; called by muse, mutect2, varscan2
- ROBO2 | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 79/211 reads (37%) | catalogued as rs1005812838, COSV59919519; called by muse, mutect2, varscan2
- XIRP2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 114/287 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs745669656, COSV99740660; called by muse, mutect2, varscan2
- ZSCAN10 | c.773C>T p.A258V (on ENST00000252463; = p.A313V on NM_032805.3) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs759881297, COSV52967103; called by muse, varscan2
- CPAMD8 | c.521del p.G174Afs*21 (on ENST00000651564; = p.G127Afs*21 on NM_015692.5) | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.2475C>T p.P825= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as rs749043144, COSV56976070; called by muse, mutect2
- C5orf38 | c.262C>T p.L88= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100121642; called by muse, mutect2, varscan2
- TSPOAP1 | c.3147G>T p.L1049= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV99270510; called by muse, mutect2, varscan2
- ACBD4 | chr17:45143476 C>T | 3'Flank (SNP) | VAF 20/104 reads (19%) | catalogued as COSV100203429; called by muse, mutect2
